Somatic mutation profile of tumor specimen MP2PRT-PATETL-TMP1-A (aliquot MP2PRT-PATETL-TMP1-A-1-0-D-A81O-36) from MP2PRT case MP2PRT-PATETL, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.3 years (1,583 days).
Specimen MP2PRT-PATETL-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e2785ee-4a53-4a70-aa8d-0d64c05eb231.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATETL-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATETL-NB1-A-1-0-D-A81O-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6054347-9739-4f73-98af-f3901ed19eb8

The open-access MAF lists 6 somatic variants for this specimen: 1 protein-altering or splice-affecting, 5 silent.
By variant classification: Silent 5, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC92 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 279/922 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.451); catalogued as rs1437247239, COSV53021936; called by muse, mutect2, varscan2
- ACP7 | c.1242G>A p.S414= | Silent (SNP) | VAF 38/552 reads (7%) | catalogued as rs151134063; called by muse, mutect2
- COL4A2 | c.2073G>T p.L691= | Silent (SNP) | VAF 124/467 reads (27%) | called by muse, mutect2, varscan2
- ITGA3 | c.3147C>T p.D1049= | Silent (SNP) | VAF 118/386 reads (31%) | catalogued as rs773168436; called by muse, varscan2
- NMT1 | c.846T>A p.T282= | Silent (SNP) | VAF 200/487 reads (41%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.1377C>T p.S459= | Silent (SNP) | VAF 192/498 reads (39%) | catalogued as rs532690347, COSV62417359; called by muse, mutect2, varscan2
